TCGA case TCGA-HT-7855 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western - St Joes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/40343ebd-0d62-401e-83a4-6cdb57662ec0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 39 years; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, anaplastic: ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 39.7 years (14,496 days); Year of diagnosis: 2008; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 585 days (1.6 years); First symptom longest duration: 91-180 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Parietal; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 73 days; Treatment dose: 5,940 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 67 days; Number of cycles: 1; Treatment dose: 6,880 mg; Prescribed dose: 160; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 131 days; Days to treatment end: 157 days; Number of cycles: 2; Treatment dose: 4,000 mg; Prescribed dose: 400; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.

Follow-up (3 entries)
- Days to follow up: 118 days; Disease response: Tumor Free.
- Day 151 (post adjuvant therapy): Karnofsky performance status: 80.
- Days to follow up: 585 days (1.6 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Altered Mental Status / Motor / Movement Change.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HT-7855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1.5; Shortest dimension: 0.6.
  Slide TCGA-HT-7855-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-HT-7855-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-HT-7855-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HT-7855-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Parietal Lobe; History seizures: No; History headaches: Yes; Symp changes mental status: Yes; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: Yes; First symptom longest duration: 91 - 180 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No.
- Drug treatment 1: Regimen number: 2; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 585 days; disease-specific survival: no event (censored), 585 days; disease-free interval: no event (censored), 585 days; progression-free interval: no event (censored), 585 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HT-7855-01A-11D-2391-01): tumor purity 0.91, ploidy 2.03, whole-genome doublings 0.
